Somatic mutation profile of tumor specimen ALCH-AFFF-TTP1-A (aliquot ALCH-AFFF-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AFFF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,172 days).
Specimen ALCH-AFFF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc734b81-c752-4151-a36c-5389e4954d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFF-NB1-A (Blood Derived Normal), aliquot ALCH-AFFF-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf855639-f4c7-4f65-9349-21258d8d44de

The open-access MAF lists 222 somatic variants for this specimen: 142 protein-altering or splice-affecting, 45 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 45, Intron 15, Nonsense Mutation 10, Frame Shift Del 7, 5'UTR 6, RNA 6, 3'UTR 5, Splice Site 3, Frame Shift Ins 3, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 78/599 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 86/663 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99447627; called by muse, mutect2
- ABCD2 | c.1237-1G>T p.X413_splice | Splice Site (SNP) | VAF 15/196 reads (8%) | catalogued as rs779299135, COSV100429520; called by muse, mutect2
- ACSM2A | c.5A>G p.H2R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1298909360; called by muse, mutect2
- ACTG2 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.07); catalogued as rs199696794; called by muse, mutect2, varscan2
- ADAMTS7 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66308118; called by muse, mutect2, varscan2
- ANXA2 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60317902; called by muse, mutect2
- ARID2 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 57/754 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57598812; called by muse, mutect2
- C8orf76 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99415071; called by muse, mutect2, varscan2
- CDH11 | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs200439593; called by muse, mutect2
- COX15 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 83/704 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1403121039; called by muse, mutect2, varscan2
- CRB1 | c.3296C>A p.T1099K | Missense Mutation (SNP) | VAF 200/1005 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as CM1111051, COSV66334867; called by muse, mutect2, varscan2
- CYREN | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV99313316; called by muse, mutect2, varscan2
- EFCAB8 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as rs1212750142; called by muse, mutect2, varscan2
- ENOX2 | c.997G>C p.E333Q (on ENST00000338144 / NM_001382520.1; = p.E304Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV57655958; called by muse, varscan2
- FAM107B | c.52C>T p.Q18* (on ENST00000378458 / NM_001320737.1; = p.Q193* on NM_031453.3) | Nonsense Mutation (SNP) | VAF 34/630 reads (5%) | catalogued as COSV51693931; called by muse, mutect2
- FAM171B | c.2257T>A p.C753S | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV59001278; called by muse, mutect2, varscan2
- FIGNL2 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs538261719; called by muse, mutect2
- GFRAL | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 46/734 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV61229179; called by muse, mutect2
- GLCCI1 | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); catalogued as rs776980379; called by muse, mutect2, varscan2
- GPATCH1 | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50122356; called by muse, mutect2
- GSG1L2 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs973842154; called by muse, mutect2, varscan2
- HIC1 | c.2078C>A p.P693Q (on ENST00000322941 / NM_001098202.1; = p.P674Q on NM_006497.4) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1175479430; called by muse, mutect2, varscan2
- IFT122 | c.521del p.G174Afs*22 (on ENST00000348417 / NM_052989.3; = p.G174Afs*36 on NM_018262.4) | Frame Shift Del (DEL) | VAF 84/544 reads (15%) | catalogued as rs751753419, COSV56203136; called by pindel, varscan2
- IL5RA | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs779048261; called by muse, mutect2, varscan2
- KMT2A | c.4411C>A p.L1471M | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs141812809; called by muse, mutect2
- KRTAP13-2 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1185771621; called by muse, mutect2
- LZTS2 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV64651370; called by muse, mutect2
- MDN1 | c.8539C>G p.R2847G | Missense Mutation (SNP) | VAF 51/594 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV65528802; called by muse, mutect2
- MMP3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs782531877; called by muse, mutect2
- MUC12 | c.14548C>T p.R4850C (on ENST00000379442; = p.R4707C on NM_001164462.1) | Missense Mutation (SNP) | VAF 71/550 reads (13%) | SIFT deleterious, low confidence (0.04); catalogued as rs778652108; called by muse, mutect2, varscan2
- MYO18B | c.6731C>T p.P2244L | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59140662; called by muse, mutect2, varscan2
- NAE1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 40/417 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.8); catalogued as rs986934942; called by muse, mutect2
- NFXL1 | c.1330-1G>A p.X444_splice | Splice Site (SNP) | VAF 17/213 reads (8%) | catalogued as COSV61200669; called by muse, mutect2
- NLRP13 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 65/526 reads (12%) | catalogued as rs372124894; called by muse, mutect2, varscan2
- NPHS2 | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 179/802 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as CM070221; called by muse, mutect2, varscan2
- OGDHL | c.2674G>T p.G892* | Nonsense Mutation (SNP) | VAF 29/236 reads (12%) | catalogued as COSV65100845, COSV65103709; called by muse, mutect2, varscan2
- OR14A16 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV62927109; called by muse, mutect2, varscan2
- OR4N5 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 20/314 reads (6%) | catalogued as rs1284888758; called by muse, mutect2
- OTOF | c.5611G>A p.G1871R (on ENST00000272371 / NM_194248.3; = p.G1104R on NM_004802.4) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs147781377; called by muse, mutect2, varscan2
- OTOR | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1229617359; called by muse, mutect2, varscan2
- PKD1 | c.10921G>A p.A3641T (on ENST00000262304 / NM_001009944.3; = p.A3640T on NM_000296.4) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs751281167; called by muse, mutect2, varscan2
- PRKCB | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100335375; called by muse, mutect2
- PTH2 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1225902190; called by muse, varscan2
- RALGAPA2 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 40/522 reads (8%) | catalogued as rs368804478; called by muse, mutect2
- RGS22 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62659716; called by muse, mutect2, varscan2
- SDK2 | c.2108C>A p.T703N | Missense Mutation (SNP) | VAF 54/523 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101167350; called by muse, mutect2, varscan2
- SHANK1 | c.1598del p.G533Afs*30 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as COSV53249798; called by mutect2, pindel, varscan2
- SLAMF7 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 101/635 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as rs1225092821; called by muse, mutect2, varscan2
- SQLE | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs760505492; called by muse, mutect2
- SYCE1L | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs1055717836; called by muse, mutect2
- TNKS2 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs966364515, COSV65416173; called by muse, mutect2, varscan2
- TRPC7 | c.1634C>A p.A545E | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61458276; called by muse, mutect2, varscan2
- TULP1 | c.83del p.P28Rfs*14 | Frame Shift Del (DEL) | VAF 19/192 reads (10%) | catalogued as COSV100003869; called by mutect2, pindel
- UNC5C | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 44/437 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs761436712, COSV71660708; called by muse, mutect2
- ZNF431 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 50/665 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60675905; called by muse, mutect2
- ABCB1 | c.695G>C p.W232S | Missense Mutation (SNP) | VAF 75/638 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- AMBP | c.7A>G p.S3G | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- ANKRD36 | c.2630A>T p.K877M | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANO5 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- ASPM | c.10162G>T p.D3388Y | Missense Mutation (SNP) | VAF 124/576 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ASXL3 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ATAD5 | c.5099G>A p.W1700* | Nonsense Mutation (SNP) | VAF 51/367 reads (14%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1295G>T p.S432I | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- C9orf153 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CBLN2 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- CCDC110 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- CDKL4 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEACAM3 | c.626C>G p.S209W | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CEMIP | c.3101T>A p.L1034H | Missense Mutation (SNP) | VAF 74/508 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHML | c.1724A>G p.Y575C | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLASP1 | c.4523G>T p.G1508V | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLASP1 | c.4522G>T p.G1508W | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNKSR3 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CSMD3 | c.6261C>A p.H2087Q (on ENST00000297405 / NM_001363185.1; = p.H1983Q on NM_052900.3) | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- CXCL9 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2
- DHRS11 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); called by muse, mutect2
- DIDO1 | c.6562G>T p.D2188Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ELOA | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 41/719 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- F5 | c.1444A>T p.T482S | Missense Mutation (SNP) | VAF 191/810 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- FAM184B | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM189A1 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, varscan2
- FAM71A | c.221C>A p.A74E | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- FHL5 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- FIS1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FOS | c.1142_1143insT p.*381Cfs*35 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- GABRR1 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GAL3ST4 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- GALNT13 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 74/548 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GPATCH1 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPD2 | c.1194G>A p.W398* | Nonsense Mutation (SNP) | VAF 105/680 reads (15%) | called by muse, mutect2, varscan2
- KCNH5 | c.326T>A p.M109K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- KNOP1 | c.1016T>A p.I339N | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- KRT25 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 31/461 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- LEF1 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 39/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LILRA1 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 90/503 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, varscan2
- LRP12 | c.852T>A p.N284K | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- MED12 | c.2800C>G p.H934D | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- METRN | c.566-1G>T p.X189_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- MSLN | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.26312C>A p.T8771N | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- MYT1L | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2
- NBAS | c.6509A>T p.E2170V | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2
- NF1 | c.1849del p.A617Qfs*14 | Frame Shift Del (DEL) | VAF 90/717 reads (13%) | called by mutect2, pindel, varscan2
- NID2 | c.2884C>A p.Q962K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NR1H4 | c.156A>T p.E52D (on ENST00000551379 / NM_001206993.2; = p.E42D on NM_005123.4) | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- NRARP | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- OR10T2 | c.562T>A p.L188I | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- PCDH7 | c.2494A>T p.T832S | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); called by muse, mutect2
- PCNX3 | c.2822G>T p.G941V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDGFRL | c.1116del p.E373Sfs*10 | Frame Shift Del (DEL) | VAF 37/253 reads (15%) | called by mutect2, pindel, varscan2
- PLCB1 | c.3299G>A p.R1100Q | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2
- POT1 | c.220A>T p.K74* | Nonsense Mutation (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- POU2F2 | c.481dup p.R161Pfs*39 (on ENST00000526816 / NM_001207025.3; = p.R161Pfs*23 on NM_002698.5) | Frame Shift Ins (INS) | VAF 36/366 reads (10%) | called by mutect2, pindel
- PRXL2A | c.647_662del p.A216Dfs*56 | Frame Shift Del (DEL) | VAF 28/309 reads (9%) | called by mutect2, pindel
- PTGS1 | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PTPRA | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2
- RNF111 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 113/749 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- RNF151 | c.404A>C p.Q135P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, varscan2
- ROCK2 | c.4024A>C p.S1342R | Missense Mutation (SNP) | VAF 35/544 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- RP1L1 | c.4313C>G p.S1438C | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RTN1 | c.1149G>C p.R383S | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- SBF1 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- SHANK1 | c.2765C>A p.P922Q | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLAMF7 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 86/448 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SLC17A8 | c.1491C>G p.F497L | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2
- SLC25A20 | c.428_432del p.S143Wfs*39 | Frame Shift Del (DEL) | VAF 69/551 reads (13%) | called by mutect2, pindel, varscan2
- SLC7A5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- SMARCA4 | c.3766dup p.Q1256Pfs*3 | Frame Shift Ins (INS) | VAF 37/292 reads (13%) | called by mutect2, pindel, varscan2
- SMPDL3B | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 57/739 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SOS2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- SOX17 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, varscan2
- STX3 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 43/543 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.379); called by muse, mutect2
- SYT6 | c.1460G>T p.R487L (on ENST00000610222 / NM_001366225.1; = p.R402L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TGFBRAP1 | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- TMEM135 | c.682A>T p.K228* | Nonsense Mutation (SNP) | VAF 138/950 reads (15%) | called by muse, mutect2, varscan2
- TRO | c.3431G>T p.G1144V | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- UBB | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2
- USH2A | c.13736T>A p.I4579N | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.124); called by muse, mutect2
- XPR1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF431 | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 50/660 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA13 | c.1302C>T p.N434= | Silent (SNP) | VAF 26/311 reads (8%) | catalogued as rs559926336; called by muse, mutect2
- AMDHD2 | c.927A>G p.G309= | Silent (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- ARIH1 | c.252C>T p.G84= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1240137621, COSV101158883; called by muse, varscan2
- CACNG6 | c.684C>A p.G228= (on ENST00000252729 / NM_145814.1; = p.G157= on NM_031897.2) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53165822; called by mutect2, varscan2
- CHCHD1 | c.351C>T p.L117= | Silent (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- CHD2 | c.4095T>A p.S1365= | Silent (SNP) | VAF 36/272 reads (13%) | called by muse, mutect2, varscan2
- DSE | c.1602G>C p.V534= | Silent (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2, varscan2
- ELAVL4 | c.852T>G p.L284= | Silent (SNP) | VAF 13/265 reads (5%) | called by muse, mutect2
- ENPP7 | c.405G>C p.L135= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV60386835; called by muse, mutect2, varscan2
- FANCI | c.342T>C p.S114= | Silent (SNP) | VAF 54/810 reads (7%) | called by muse, mutect2
- FFAR3 | c.645C>T p.G215= | Silent (SNP) | VAF 44/330 reads (13%) | catalogued as rs1185002637; called by muse, mutect2, varscan2
- FILIP1 | c.1293A>G p.R431= | Silent (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- FLG | c.1770A>G p.E590= | Silent (SNP) | VAF 38/796 reads (5%) | called by muse, mutect2
- HRNR | c.7086T>A p.G2362= | Silent (SNP) | VAF 85/2916 reads (3%) | called by muse, mutect2
- KCNH5 | c.324T>C p.Y108= | Silent (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- KLK10 | c.495C>T p.P165= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs753173361; called by muse, mutect2, varscan2
- KNDC1 | c.3075G>T p.L1025= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- KRT13 | c.168G>T p.G56= | Silent (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- LDB2 | c.603C>T p.L201= | Silent (SNP) | VAF 29/343 reads (8%) | called by muse, mutect2
- LRP4 | c.1671G>A p.R557= | Silent (SNP) | VAF 40/309 reads (13%) | catalogued as rs1223336072; called by muse, mutect2, varscan2
- MED24 | c.90C>T p.F30= | Silent (SNP) | VAF 65/460 reads (14%) | catalogued as COSV100673336, COSV62416993; called by muse, mutect2, varscan2
- MUC5B | c.16992G>T p.T5664= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- NYNRIN | c.147C>T p.P49= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs773082691; called by muse, mutect2, varscan2
- OR5W2 | c.498A>G p.L166= | Silent (SNP) | VAF 11/192 reads (6%) | catalogued as rs1370181785; called by muse, mutect2
- OR6K6 | c.546C>A p.L182= (on ENST00000368144; = p.L158= on NM_001005184.1) | Silent (SNP) | VAF 45/315 reads (14%) | catalogued as COSV63745049; called by muse, mutect2, varscan2
- PACS2 | c.924C>T p.D308= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs146162539; called by muse, mutect2, varscan2
- PAX4 | c.133C>A p.R45= | Silent (SNP) | VAF 71/516 reads (14%) | catalogued as CM043321; called by muse, mutect2, varscan2
- PCDHA7 | c.1923C>T p.D641= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as rs1554135806, COSV65342003; called by muse, mutect2, varscan2
- PCDHB6 | c.1218G>T p.A406= | Silent (SNP) | VAF 44/337 reads (13%) | catalogued as rs142222504, COSV50691927; called by muse, mutect2, varscan2
- PCDHGB2 | c.1494G>A p.P498= | Silent (SNP) | VAF 49/299 reads (16%) | catalogued as COSV54010700; called by muse, mutect2, varscan2
- PLA2G6 | c.2031C>T p.R677= | Silent (SNP) | VAF 71/420 reads (17%) | called by muse, mutect2, varscan2
- PLCB1 | c.3297C>A p.I1099= | Silent (SNP) | VAF 45/431 reads (10%) | catalogued as COSV62049022; called by muse, mutect2
- POT1 | c.1189T>C p.L397= | Silent (SNP) | VAF 47/452 reads (10%) | catalogued as COSV100714054; called by muse, mutect2, varscan2
- PYGB | c.1296C>T p.I432= | Silent (SNP) | VAF 67/303 reads (22%) | catalogued as rs201366222; called by muse, mutect2, varscan2
- RALGAPA1 | c.132A>G p.K44= | Silent (SNP) | VAF 15/298 reads (5%) | called by muse, mutect2
- REPS1 | c.417G>C p.V139= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- SLC30A10 | c.243C>A p.G81= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV63075399; called by muse, mutect2
- SLC5A5 | c.684G>T p.R228= | Silent (SNP) | VAF 72/381 reads (19%) | called by muse, mutect2, varscan2
- TECPR1 | c.2004G>T p.V668= | Silent (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- TKTL2 | c.999C>A p.G333= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV54918688; called by muse, mutect2
- TMEM132D | c.1797C>A p.G599= | Silent (SNP) | VAF 37/219 reads (17%) | called by muse, mutect2, varscan2
- TRIM9 | c.1368C>T p.N456= | Silent (SNP) | VAF 39/335 reads (12%) | called by muse, mutect2, varscan2
- TRPV5 | c.468C>A p.P156= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- ZBTB1 | c.498G>A p.T166= | Silent (SNP) | VAF 26/372 reads (7%) | catalogued as rs188036695, COSV62438514; called by muse, mutect2
- ZNF85 | c.444T>C p.C148= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+11411T>C | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- ADCY10 | c.-17G>T | 5'UTR (SNP) | VAF 44/764 reads (6%) | called by muse, mutect2
- AP000769.5 | chr11:65499569 A>T | 5'Flank (SNP) | VAF 26/421 reads (6%) | called by muse, mutect2
- ATP8A2 | c.-56C>G | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, varscan2
- BIN1 | c.1263+12G>T | Intron (SNP) | VAF 54/429 reads (13%) | called by muse, mutect2, varscan2
- C3orf35 | n.1251C>T | RNA (SNP) | VAF 49/263 reads (19%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+34T>C | Intron (SNP) | VAF 36/625 reads (6%) | catalogued as rs770169562; called by muse, mutect2
- DRAM1 | c.132-7742C>G | Intron (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- FIS1 | c.-42C>G | 5'UTR (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2, varscan2
- GYPC | c.*34C>A | 3'UTR (SNP) | VAF 32/441 reads (7%) | called by muse, mutect2
- IGFN1 | c.1241+2925del | Intron (DEL) | VAF 79/328 reads (24%) | called by mutect2, pindel, varscan2
- KCNB1 | c.-148G>C | 5'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- LINC00452 | n.668G>C | RNA (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- LINC02448 | n.336C>A | RNA (SNP) | VAF 40/552 reads (7%) | called by muse, mutect2
- LIPC | c.1388+22T>A | Intron (SNP) | VAF 68/439 reads (15%) | called by muse, mutect2, varscan2
- LRRC27 | c.1073+1175T>C | Intron (SNP) | VAF 36/520 reads (7%) | called by muse, mutect2
- LRRC74A | c.217+100C>T | Intron (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- MATK | c.*11T>A | 3'UTR (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- MIR1197 | n.22C>A | RNA (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- MKRN9P | n.557C>A | RNA (SNP) | VAF 60/383 reads (16%) | called by muse, mutect2, varscan2
- NCAN | c.*96A>C | 3'UTR (SNP) | VAF 75/452 reads (17%) | called by muse, mutect2, varscan2
- NR5A2 | c.1110+8769G>T | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as rs1409471849; called by muse, mutect2, varscan2
- PPARG | c.83-7814G>A | Intron (SNP) | VAF 64/447 reads (14%) | called by muse, mutect2, varscan2
- PSG6 | c.-2C>A | 5'UTR (SNP) | VAF 56/249 reads (22%) | catalogued as rs375789064, COSV51830316; called by muse, mutect2, varscan2
- SFRP1 | c.623-9702G>T | Intron (SNP) | VAF 17/326 reads (5%) | called by muse, mutect2
- SNORD114-3 | n.20G>T | RNA (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- SRSF10 | c.438-26A>C | Intron (SNP) | VAF 42/616 reads (7%) | called by muse, mutect2
- STUB1 | chr16:684421 C>A | 3'Flank (SNP) | VAF 9/82 reads (11%) | catalogued as rs767335420; called by muse, mutect2, varscan2
- SYT14 | c.*741C>T | 3'UTR (SNP) | VAF 94/460 reads (20%) | called by muse, mutect2, varscan2
- TCF25 | c.614+1577C>T | Intron (SNP) | VAF 18/179 reads (10%) | catalogued as rs908712309; called by muse, mutect2, varscan2
- TMEM70 | c.*608G>T | 3'UTR (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- TRAV10 | c.-18G>T | 5'UTR (SNP) | VAF 75/383 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.10360+3145C>G | Intron (SNP) | VAF 94/641 reads (15%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3788C>A | Intron (SNP) | VAF 90/777 reads (12%) | called by muse, mutect2, varscan2
- ZNF625 | chr19:12142495 G>T | 3'Flank (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
